Gene-level copy-number profile of tumor specimen HTMCP-03-06-02340-01A from CGCI case HTMCP-03-06-02340, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Age at diagnosis: 48.5 years (17,732 days).
Specimen HTMCP-03-06-02340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 979d6ef9-860d-4a0e-9e42-8eb2f2ddd34c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02340-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/8cc89d2b-9fa4-4bd0-843b-9856852fdcd4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 2; copy number 2: 2,275; copy number 3: 12,397; copy number 4: 35,541; copy number 5: 5,591; copy number 6: 269; copy number 7: 1,119; copy number 8: 555; copy number 9: 363; copy number 10: 4; copy number 11: 204; copy number 12: 6; copy number 22: 2; copy number 26: 39.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:103,402,013–104,164,379, 12 genes (within-gene range 0–22): MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 618 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:14,143,342–17,670,571, 85 genes, copy number 9 (broad region; genes not listed).
- chr5:31,053,565–44,066,731, 228 genes, copy number 9 (broad region; genes not listed).
- chr7:38,269,491–38,300,322, 6 genes, copy number 12 (within-gene range 8–12): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr11:101,890,674–103,479,863, 41 genes, copy number 22–26 (within-gene range 0–26): ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1.
- chr14:22,185,562–22,486,296, 35 genes, copy number 11: TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52.
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.
- chr20:31,257,664–37,241,619, 218 genes, copy number 9–11 (broad region; genes not listed).
- chr20:47,478,214–47,656,877, 4 genes, copy number 10 (within-gene range 8–10): RPL35AP, RNU6-497P, RNU6-563P, NCOA3.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
